CCDI case PBCBFB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/414bc54f-c392-4b7c-9d23-5a10447f4c08

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.9 years (2,149 days).

Biospecimens (3 samples)
- Sample 0DN3R6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DN3SB, 0DN3ST (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
